Somatic mutation profile of tumor specimen 0DWQ4J from CCDI case PBCPLJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (579 days).
Specimen 0DWQ4J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9309e600-9270-4056-88ad-c3c0a937d677.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWQ3X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/677e37ff-c45c-4b46-9018-52ba13484337

The open-access MAF lists 30 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, 5'UTR 2, Intron 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.1361C>T p.A454V (on ENST00000326724 / NM_001080395.3; = p.A351V on NM_004920.2) | Missense Mutation (SNP) | VAF 29/572 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as rs1309579096; called by muse, mutect2
- CD300A | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 24/896 reads (3%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.648); catalogued as COSV60411267; called by muse, mutect2
- MUC16 | c.37491G>C p.R12497S | Missense Mutation (SNP) | VAF 66/766 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV101202192; called by muse, mutect2
- NECTIN2 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 17/561 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392500163; called by muse, mutect2
- OR4A5 | c.335T>A p.L112H | Missense Mutation (SNP) | VAF 36/709 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100157333; called by muse, mutect2
- SLC6A16 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 52/552 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.498); catalogued as rs1309444331; called by muse, mutect2
- SYNPO2 | c.2066G>A p.R689K | Missense Mutation (SNP) | VAF 62/1459 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.432); catalogued as COSV100206558; called by muse, mutect2
- THSD7A | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 22/748 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.439); catalogued as COSV101439726; called by muse, mutect2
- ARHGAP32 | c.5513G>A p.R1838K (on ENST00000310343 / NM_001378025.1; = p.R1489K on NM_014715.4) | Missense Mutation (SNP) | VAF 71/589 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CSMD3 | c.3463G>A p.A1155T (on ENST00000297405 / NM_001363185.1; = p.A1051T on NM_052900.3) | Missense Mutation (SNP) | VAF 57/624 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); called by muse, mutect2
- KCNJ3 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 92/1129 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- NDUFB11 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 80/1295 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.022); called by muse, mutect2
- OSBPL7 | c.166A>C p.K56Q | Missense Mutation (SNP) | VAF 28/503 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- PSKH2 | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 36/578 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.348); called by muse, mutect2
- SHROOM2 | c.996C>G p.H332Q | Missense Mutation (SNP) | VAF 35/1006 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- SULF2 | c.82C>G p.H28D | Missense Mutation (SNP) | VAF 37/1226 reads (3%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); called by muse, mutect2
- AC013477.1 | c.2487C>T p.D829= | Silent (SNP) | VAF 98/1350 reads (7%) | called by muse, mutect2
- AKAP7 | c.921G>T p.A307= (on ENST00000431975 / NM_016377.4; = p.A40= on NM_004842.4) | Silent (SNP) | VAF 73/546 reads (13%) | catalogued as COSV53833559; called by muse, mutect2, varscan2
- C10orf71 | c.393C>A p.S131= | Silent (SNP) | VAF 513/1184 reads (43%) | called by muse, mutect2, varscan2
- GPR141 | c.663C>T p.F221= | Silent (SNP) | VAF 20/628 reads (3%) | called by muse, mutect2
- HSPA1L | c.1491C>T p.T497= | Silent (SNP) | VAF 22/524 reads (4%) | catalogued as rs747155986; called by muse, mutect2
- KRT72 | c.231C>A p.T77= | Silent (SNP) | VAF 28/934 reads (3%) | catalogued as rs1460230069; called by muse, mutect2
- PFKFB1 | c.453T>G p.G151= | Silent (SNP) | VAF 32/1215 reads (3%) | called by muse, mutect2
- RAD52 | c.1038G>A p.S346= | Silent (SNP) | VAF 369/827 reads (45%) | catalogued as rs374156479; called by muse, mutect2, varscan2
- CADPS | c.3477+20_3477+24delinsAAAAAAAAAAAAAAAAAAA | Intron (INS) | VAF 3/23 reads (13%) | called by mutect2*, pindel
- CSTF2 | c.-21G>A | 5'UTR (SNP) | VAF 44/470 reads (9%) | catalogued as rs1189557476; called by muse, mutect2
- PDCD6IP | c.2026-99C>G | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- SOGA1 | c.*8583C>T | 3'UTR (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- TAC1 | c.*63A>G | 3'UTR (SNP) | VAF 15/213 reads (7%) | called by muse, mutect2
- UGT1A6 | c.-35T>C | 5'UTR (SNP) | VAF 20/666 reads (3%) | called by muse, mutect2
